Somatic mutation profile of tumor specimen TCGA-55-6969-01A (aliquot TCGA-55-6969-01A-11D-1945-08) from TCGA case TCGA-55-6969, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.8 years (19,270 days).
Specimen TCGA-55-6969-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23472ce9-116c-46b6-812c-5fdf93d253e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6969-11A (Solid Tissue Normal), aliquot TCGA-55-6969-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e89e242-69ef-4c82-8069-460a36bed8e1

The open-access MAF lists 428 somatic variants for this specimen: 327 protein-altering or splice-affecting, 88 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 88, Nonsense Mutation 22, Frame Shift Del 9, RNA 9, Frame Shift Ins 7, Splice Site 6, Intron 3, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCB1 | c.3055G>T p.D1019Y | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55948664; called by muse, mutect2, varscan2
- ABCB1 | c.308T>A p.F103Y | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55948673; called by muse, mutect2, varscan2
- ABCB11 | c.1890A>T p.E630D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.177); catalogued as COSV55588450; called by muse, mutect2, varscan2
- AC100868.1 | c.788A>T p.Q263L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51840808; called by muse, mutect2, varscan2
- ACAP1 | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV50134868; called by muse, mutect2, varscan2
- ACTRT3 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1232808523, COSV57754190; called by muse, mutect2, varscan2
- ADAMTS6 | c.2436+1G>A p.X812_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as COSV66858661; called by muse, varscan2
- ADAMTSL1 | c.1831T>C p.W611R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52813449; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54443043, COSV54454489; called by muse, mutect2, varscan2
- ADH1C | c.844T>C p.C282R | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV72463429; called by muse, mutect2, varscan2
- ADO | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV65677781; called by muse, mutect2, varscan2
- AGBL2 | c.1712G>T p.C571F | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54091214; called by muse, mutect2, varscan2
- AGMO | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61109774; called by muse, mutect2, varscan2
- AHNAK2 | c.5987C>T p.P1996L | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs564650117, COSV60912563; called by muse, mutect2, varscan2
- ALMS1 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV52507357; called by muse, mutect2, varscan2
- ANK2 | c.4601T>A p.V1534E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as COSV52155078; called by muse, mutect2, varscan2
- ANKLE1 | c.1316G>T p.R439M (on ENST00000394458; = p.R385M on NM_152363.6) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV100845718, COSV63920358; called by muse, mutect2, varscan2
- ANKRD27 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV60130678; called by muse, mutect2, varscan2
- ANO2 | c.2476C>A p.P826T (on ENST00000356134 / NM_001278597.3; = p.P830T on NM_001278596.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100502649, COSV59016421; called by muse, mutect2
- APOB | c.2726C>A p.S909* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV51931224; called by muse, mutect2, varscan2
- ARHGAP15 | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV54489085; called by muse, varscan2
- ASXL3 | c.3826G>C p.A1276P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV52462882; called by muse, mutect2, varscan2
- ATP5F1A | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as rs1382757381, COSV56360080, COSV56360152; called by muse, mutect2
- ATP6V1B1 | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); catalogued as COSV99314472; called by muse, mutect2, varscan2
- AZGP1 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 121/468 reads (26%) | catalogued as COSV52797492; called by muse, mutect2, varscan2
- B4GALT6 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as COSV52703157; called by muse, varscan2
- BACH2 | c.425T>A p.V142E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV57589318; called by muse, mutect2, varscan2
- BCL2 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as rs1284045765, COSV61377649; called by muse, mutect2, varscan2
- BICC1 | c.2512A>C p.K838Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV54062991; called by muse, mutect2, varscan2
- BRINP1 | c.2255A>G p.Q752R | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.341); catalogued as COSV56295238, COSV56296949; called by muse, mutect2
- C1QA | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV65889476; called by mutect2, varscan2
- C1QTNF8 | c.165del p.L56Cfs*8 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs1190407234; called by mutect2, pindel, varscan2
- CACNA1S | c.4103G>A p.C1368Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs780152205, COSV62938462; called by mutect2, varscan2
- CADM1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV59007342; called by muse, varscan2
- CAMSAP1 | c.2365A>C p.S789R | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56721134; called by muse, mutect2, varscan2
- CAPRIN1 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV58219318; called by muse, mutect2, varscan2
- CCDC110 | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1229681208, COSV56870301; called by muse, mutect2, varscan2
- CDH18 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV56913662; called by mutect2, varscan2
- CDH19 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV50956632; called by muse, mutect2, varscan2
- CEP192 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV58062431; called by mutect2, varscan2
- CES5A | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV51865410; called by muse, mutect2, varscan2
- CHD7 | c.2922G>T p.E974D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71108909; called by muse, mutect2, varscan2
- CHRNA3 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV58774687; called by muse, mutect2
- CLCN1 | c.1062C>A p.I354= | Splice Region (SNP) | VAF 25/80 reads (31%) | catalogued as COSV58368927; called by muse, mutect2, varscan2
- CLEC17A | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60427336, COSV60427423; called by muse, mutect2, varscan2
- CLEC4F | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55478925; called by mutect2, varscan2
- CNGA4 | c.1551G>C p.E517D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV66005621; called by muse, mutect2, varscan2
- CNTN1 | c.1552G>T p.V518F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61638430; called by muse, mutect2, varscan2
- CNTN1 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61638439; called by muse, mutect2, varscan2
- CNTN4 | c.2419A>G p.S807G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV61871089; called by muse, mutect2
- COL9A2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101028747, COSV65622869; called by muse, mutect2, varscan2
- COX10 | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as COSV55404155; called by muse, mutect2, varscan2
- CPA1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.384); catalogued as COSV50568810; called by muse, mutect2, varscan2
- CRABP2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs771785983, COSV63958778; called by mutect2, varscan2
- CSMD2 | c.3923G>A p.C1308Y | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.699); catalogued as COSV53900235; called by muse, mutect2, varscan2
- CST1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV59054994; called by muse, mutect2, varscan2
- CTTNBP2 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV50394984, COSV99354428; called by muse, mutect2, varscan2
- DAB2 | c.983C>G p.S328C | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100298293; called by muse, mutect2
- DACH2 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV64165878; called by muse, mutect2, varscan2
- DDX54 | c.719G>T p.S240I | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV58372853; called by muse, varscan2
- DDX54 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV58372867; called by muse, varscan2
- DDX60 | c.2476G>T p.A826S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV67096136; called by muse, mutect2, varscan2
- DEFB115 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV68723024, COSV68723059; called by muse, mutect2, varscan2
- DHX34 | c.2871G>T p.Q957H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.687); catalogued as rs1257235731, COSV60895019; called by muse, mutect2, varscan2
- DLC1 | c.3585C>A p.D1195E (on ENST00000276297 / NM_001348081.2; = p.D758E on NM_006094.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV52298324; called by muse, mutect2, varscan2
- DMGDH | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV99669467; called by muse, mutect2, varscan2
- DMXL2 | c.5191G>T p.A1731S | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51843935, COSV51853540; called by muse, mutect2, varscan2
- DNAH3 | c.5939G>T p.R1980L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772935570, COSV54514901; called by mutect2, varscan2
- DNAJC14 | c.331A>C p.N111H | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV57912705; called by muse, mutect2
- DNM3 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV62456002; called by muse, mutect2, varscan2
- DNTT | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV64522857; called by muse, mutect2, varscan2
- DZIP1L | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59520094; called by muse, mutect2, varscan2
- EFNA4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1558139918, COSV99664890, COSV99664950; called by muse, mutect2, varscan2
- EHBP1 | c.2257A>G p.I753V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1335517104, COSV50418409; called by muse, mutect2, varscan2
- EHF | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV57667980; called by muse, mutect2, varscan2
- EP300 | c.4513G>T p.E1505* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54330446, COSV54348775; called by muse, mutect2
- EP400 | c.2341G>T p.E781* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV57768985; called by mutect2, varscan2
- EPB41L4B | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV65802647, COSV65805147; called by muse, mutect2, varscan2
- ERICH3 | c.4246C>A p.P1416T | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV58603827; called by muse, mutect2, varscan2
- F2R | c.1164C>A p.C388* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV59928865; called by muse, mutect2, varscan2
- FBXL3 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62918611; called by muse, mutect2, varscan2
- FOLH1 | c.1807G>T p.V603F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.518); catalogued as COSV57047752; called by muse, mutect2, varscan2
- FOXJ3 | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.36); catalogued as COSV62361637; called by muse, mutect2, varscan2
- FRG2C | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.644); catalogued as rs1179297288; called by muse, mutect2
- GALNT17 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as COSV61156219; called by muse, mutect2, varscan2
- GAS7 | c.1283A>T p.Q428L (on ENST00000432992 / NM_201433.2; = p.Q288L on NM_003644.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV60434297; called by muse, mutect2, varscan2
- GCC1 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV58462216; called by muse, mutect2, varscan2
- GCNT2 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs754817260, COSV65456985; called by muse, mutect2, varscan2
- GET1 | c.490A>C p.K164Q | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as COSV61554899; called by muse, mutect2, varscan2
- GLP2R | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1323936667, COSV52323679, COSV52324132; called by muse, mutect2, varscan2
- GPR107 | c.188A>T p.K63M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV61278507; called by muse, mutect2, varscan2
- GPRIN1 | c.1930G>T p.G644W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56137037; called by muse, mutect2, varscan2
- GRIA4 | c.2261A>G p.Y754C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56889885; called by muse, mutect2, varscan2
- GRIN3A | c.1844G>C p.G615A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62452392; called by muse, mutect2, varscan2
- GRM2 | c.2032T>C p.S678P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56583977; called by muse, mutect2, varscan2
- GZMA | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV57051275; called by muse, mutect2, varscan2
- HECW1 | c.2680A>G p.T894A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV67823091; called by muse, mutect2, varscan2
- HERC2 | c.8917G>T p.G2973C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55317681, COSV55325475; called by muse, mutect2, varscan2
- HSPA12B | c.200T>A p.F67Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54766280; called by muse, varscan2
- HSPA1L | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV65150317; called by muse, mutect2, varscan2
- HTR3C | c.1254C>A p.F418L | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV59174870; called by muse, mutect2, varscan2
- HTT | c.7333G>A p.V2445I | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV61860178; called by muse, mutect2, varscan2
- IFNA6 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV66506313; called by muse, mutect2, varscan2
- IFNL2 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV59593305; called by muse, mutect2, varscan2
- IGF2R | c.3673G>T p.D1225Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63628101; called by muse, mutect2, varscan2
- IGLV2-33 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.137); catalogued as rs772354626; called by muse, mutect2, varscan2
- ILVBL | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV54618832; called by muse, mutect2, varscan2
- IRAK2 | c.1463G>T p.S488I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV56530468; called by muse, mutect2, varscan2
- ITGA4 | c.902del p.K301Sfs*50 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as COSV99275859; called by mutect2, pindel, varscan2
- ITGA5 | c.1622-2A>T p.X541_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | catalogued as COSV53216805; called by muse, mutect2, varscan2
- ITGAE | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV99561494; called by muse, mutect2, varscan2
- ITGAX | c.1579G>T p.V527L | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV51644401; called by muse, mutect2, varscan2
- ITIH6 | c.2630C>G p.P877R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as COSV54488143; called by muse, mutect2, varscan2
- ITPRID2 | c.1576-1G>T p.X526_splice | Splice Site (SNP) | VAF 11/89 reads (12%) | catalogued as COSV57470761; called by muse, mutect2, varscan2
- JPH2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60696779; called by muse, mutect2, varscan2
- KBTBD8 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV55127872; called by muse, mutect2, varscan2
- KCNH4 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs755522577, COSV52916535; called by mutect2, varscan2
- KCNJ12 | c.485T>A p.V162E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59165603; called by muse, mutect2, varscan2
- KCNJ3 | c.859A>T p.S287C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV54534598; called by muse, mutect2, varscan2
- KCNT2 | c.3157G>T p.A1053S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54073439; called by muse, mutect2, varscan2
- KDM2A | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192441513, COSV67081658; called by muse, mutect2, varscan2
- KDM5B | c.3593C>G p.A1198G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV52506656; called by muse, mutect2
- KEL | c.1038G>A p.M346I | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV62333835; called by muse, mutect2
- KIR3DL2 | c.496C>A p.R166S | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV54393896; called by muse, varscan2
- KLHDC7A | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as rs776362096, COSV68769484; called by muse, mutect2, varscan2
- LAMB1 | c.1118A>C p.N373T | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV55963517; called by muse, mutect2
- LAMB4 | c.818A>T p.E273V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV52716975; called by muse, mutect2, varscan2
- LARP1 | c.3019A>G p.I1007V (on ENST00000518297 / NM_033551.3; = p.I930V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV60426058; called by muse, mutect2, varscan2
- LILRA1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52182714; called by muse, varscan2
- LONRF1 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV68036390; called by muse, mutect2, varscan2
- LRP1B | c.11501A>T p.Q3834L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV101260318; called by muse, mutect2, varscan2
- LRRN2 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1296435462, COSV65783199, COSV65783508; called by mutect2, varscan2
- MAGEA12 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV63294549; called by muse, mutect2, varscan2
- MAGEB6 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV66872093, COSV66873453; called by muse, varscan2
- MAP2 | c.3124G>T p.V1042F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV52287084; called by muse, mutect2, varscan2
- MC3R | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54763449; called by muse, mutect2, varscan2
- MCCC2 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as CM125727, COSV60154003; called by mutect2, varscan2
- MDM4 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65795387; called by muse, mutect2, varscan2
- MED12L | c.896C>G p.A299G | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV56374988; called by muse, varscan2
- MEP1A | c.1469G>T p.S490I | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57919327; called by muse, mutect2, varscan2
- MID2 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs1324326448, COSV53308439, COSV53315500; called by muse, mutect2, varscan2
- MINK1 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.762); catalogued as COSV61789584; called by muse, mutect2, varscan2
- MINK1 | c.2793G>T p.K931N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs1480756395, COSV53417459; called by mutect2, varscan2
- MMP16 | c.1216T>C p.F406L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV54159224; called by muse, mutect2
- MRO | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV99839141, COSV99839521; called by mutect2, varscan2
- MRPL43 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52967291; called by muse, mutect2
- MS4A7 | c.710G>C p.R237P | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV55729369, COSV55729706; called by muse, mutect2, varscan2
- MSC | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57696491; called by muse, mutect2, varscan2
- MUC16 | c.27931A>G p.S9311G | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.047); catalogued as COSV67458356; called by muse, mutect2, varscan2
- MUC5B | c.3901G>A p.A1301T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs377058031, COSV71591253; called by mutect2, varscan2
- MYH10 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52598442; called by muse, mutect2
- MYH3 | c.5265G>T p.K1755N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV56863402; called by mutect2, varscan2
- MYH3 | c.4175A>G p.K1392R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs1488426810, COSV56863410; called by muse, mutect2, varscan2
- MYPN | c.3199C>A p.Q1067K | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV62732858; called by muse, mutect2, varscan2
- NAA60 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.291); catalogued as COSV62654542; called by muse, varscan2
- NCAN | c.19T>A p.W7R | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV53049516; called by muse, mutect2, varscan2
- NCKAP5 | c.4475A>T p.K1492M | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58437712; called by muse, mutect2, varscan2
- NCKAP5 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV58437718; called by muse, mutect2, varscan2
- NEB | c.7414G>C p.A2472P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51089599; called by muse, mutect2, varscan2
- NEB | c.6136G>C p.A2046P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51089919; called by mutect2, varscan2
- NEB | c.5078G>T p.W1693L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1273340751, COSV99427449; called by muse, mutect2, varscan2
- NELL2 | c.679A>C p.T227P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV61572488; called by muse, mutect2, varscan2
- NLRP13 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61621104; called by muse, mutect2
- NPAP1 | c.195del p.F65Lfs*50 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV61504060; called by mutect2, pindel, varscan2
- NRXN2 | c.5014C>A p.Q1672K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV55450951; called by muse, mutect2, varscan2
- NRXN2 | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55450970; called by muse, mutect2
- NUF2 | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV54843194, COSV54844505; called by muse, mutect2, varscan2
- NUP210L | c.2380A>T p.R794W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55145354; called by muse, mutect2, varscan2
- OCM2 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99990870; called by mutect2, varscan2
- OLFML2B | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54195544; called by muse, mutect2, varscan2
- OR13C3 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101053356; called by muse, mutect2, varscan2
- OR13C3 | c.787G>C p.G263R | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101053358; called by muse, mutect2, varscan2
- OR14C36 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58600743, COSV58602838; called by muse, mutect2
- OR2AK2 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100824318; called by mutect2, varscan2
- OR2F1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67331163; called by muse, mutect2, varscan2
- OR2H1 | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.341); catalogued as COSV65810424; called by muse, mutect2
- OR2T33 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV58814985; called by muse, varscan2
- OR2T33 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1298197518, COSV58813710; called by muse, varscan2
- OR4C13 | c.514A>T p.I172L | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as COSV73648710; called by muse, mutect2
- OR4K15 | c.184A>C p.I62L (on ENST00000305051; = p.I38L on NM_001005486.1) | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV59301009; called by muse, mutect2
- OR51F1 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100598938, COSV58579283; called by muse, mutect2, varscan2
- OR51G2 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs200340167, COSV58992456; called by muse, varscan2
- OR52A5 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614799; called by mutect2, varscan2
- OR5M3 | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56566374; called by muse, mutect2, varscan2
- OR6C3 | c.103A>C p.S35R | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV65570938; called by muse, mutect2, varscan2
- OR6N2 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV59410942; called by muse, mutect2, varscan2
- OR8I2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV56167371; called by muse, mutect2, varscan2
- OTUD6A | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57973016; called by muse, mutect2, varscan2
- P2RX5 | c.1238C>A p.P413Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV56591425; called by muse, mutect2, varscan2
- PCDH10 | c.1746C>A p.N582K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52091367; called by muse, varscan2
- PCDH15 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57289202; called by mutect2, varscan2
- PCDH19 | c.2678G>T p.S893I (on ENST00000373034 / NM_001184880.2; = p.X845_splice on NM_020766.3) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV55260675, COSV55264892; called by muse, mutect2, varscan2
- PCDHB6 | c.1741G>A p.G581S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782759466, COSV50693532; called by muse, mutect2, varscan2
- PEG3 | c.4469C>A p.P1490Q | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV55630226; called by muse, mutect2, varscan2
- PER2 | c.2522G>A p.C841Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV54522684; called by muse, mutect2, varscan2
- PEX13 | c.521A>G p.H174R | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV54369629; called by muse, mutect2, varscan2
- PEX2 | c.742G>T p.G248* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV63813352; called by muse, mutect2, varscan2
- PHF23 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); catalogued as COSV50035365; called by muse, mutect2, varscan2
- PI4KA | c.4159A>T p.S1387C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55408416; called by muse, mutect2, varscan2
- PLCXD2 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67339164; called by muse, mutect2, varscan2
- PLXNA3 | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100860193, COSV63753730, COSV63753840; called by muse, mutect2, varscan2
- PLXNA4 | c.4758C>A p.H1586Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58117040; called by muse, mutect2
- PMP22 | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as CM962680, COSV56601819; called by muse, mutect2, varscan2
- POGLUT2 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65682667; called by muse, mutect2, varscan2
- POLR1A | c.4416G>C p.E1472D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55691575; called by muse, mutect2
- POMK | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58856916; called by mutect2, varscan2
- POP1 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62892409; called by muse, mutect2, varscan2
- PPM1G | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.248); catalogued as COSV59769112; called by muse, mutect2
- PPP1R9A | c.1564G>C p.G522R | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56888338; called by muse, mutect2
- PRDM14 | c.1094G>T p.W365L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52571590; called by muse, mutect2, varscan2
- PRICKLE3 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV66234315; called by muse, mutect2, varscan2
- PSMC6 | c.138A>T p.Q46H (on ENST00000612399; = p.Q32H on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV71628679; called by mutect2, varscan2
- PTPRD | c.5396C>G p.T1799R | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61937846; called by muse, mutect2
- PTPRT | c.3494G>T p.R1165M | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61973589; called by muse, mutect2, varscan2
- PXDNL | c.1804G>C p.G602R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as COSV62484821; called by muse, mutect2, varscan2
- RAP2A | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV55354132; called by muse, mutect2, varscan2
- RASIP1 | c.2692+2T>G p.X898_splice | Splice Site (SNP) | VAF 10/103 reads (10%) | catalogued as COSV55803860; called by muse, mutect2, varscan2
- RNF138 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV55233904; called by muse, mutect2
- RNF220 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62405909; called by muse, mutect2, varscan2
- RSBN1 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV54731931, COSV54732609; called by muse, mutect2, varscan2
- RSPH6A | c.1475C>A p.T492K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769052549, COSV55570669, COSV55571101, COSV99679797; called by muse, mutect2, varscan2
- RYR2 | c.8024C>A p.A2675D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373767708, COSV63677366; called by mutect2, varscan2
- RYR2 | c.9442G>C p.V3148L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV100771577, COSV63677375; called by muse, varscan2
- RYR3 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as COSV66783935; called by muse, mutect2, varscan2
- RYR3 | c.5008C>A p.P1670T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV66780775, COSV66794072; called by mutect2, varscan2
- SAMD4A | c.1643A>C p.Q548P | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV51879054; called by muse, mutect2, varscan2
- SAMSN1 | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV53469834, COSV53474370; called by muse, mutect2, varscan2
- SCN3A | c.5011A>G p.I1671V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV51806780; called by muse, mutect2, varscan2
- SCUBE2 | c.2341+1G>T p.X781_splice (on ENST00000649792 / NM_001367977.2; = p.X724_splice on NM_020974.3) | Splice Site (SNP) | VAF 15/142 reads (11%) | catalogued as COSV58541881; called by muse, mutect2, varscan2
- SERPINB7 | c.455del p.X152_splice | Splice Site (DEL) | VAF 10/46 reads (22%) | catalogued as CS1311121; called by mutect2, pindel, varscan2
- SFXN5 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV55586120; called by mutect2, varscan2
- SGO2 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV63414783; called by muse, mutect2, varscan2
- SHC4 | c.1840A>T p.K614* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV60111012; called by muse, mutect2, varscan2
- SIPA1L3 | c.202A>G p.S68G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV55908858, COSV99730320; called by muse, mutect2, varscan2
- SLC22A12 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV60571585; called by muse, mutect2, varscan2
- SLC22A25 | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60595308; called by muse, mutect2
- SLC39A14 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV51483535; called by muse, mutect2, varscan2
- SLC9A2 | c.1108A>G p.S370G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52130785; called by muse, mutect2, varscan2
- SLC9A2 | c.1334T>C p.L445S | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52130795; called by muse, mutect2, varscan2
- SMARCA4 | c.3584A>T p.Q1195L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV60791239; called by muse, mutect2
- SMG8 | c.341_342insA p.S115Ffs*12 | Frame Shift Ins (INS) | VAF 4/15 reads (27%) | catalogued as COSV99959048; called by mutect2, varscan2
- SMG8 | c.1394A>T p.E465V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV99959050; called by muse, mutect2
- SMG8 | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV99959052; called by muse, mutect2, varscan2
- SNX25 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as COSV53013177; called by muse, mutect2, varscan2
- SPDL1 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV54667708; called by muse, mutect2, varscan2
- SPTB | c.3582G>T p.L1194F | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV67630963; called by muse, mutect2, varscan2
- STIP1 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59438877; called by muse, mutect2, varscan2
- SUCLA2 | c.1027G>C p.V343L (on ENST00000643023; = p.V322L on NM_003850.3) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV66222137; called by muse, mutect2, varscan2
- SV2C | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV59217918; called by muse, mutect2, varscan2
- SYCP2L | c.2298G>C p.E766D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV51651900; called by muse, mutect2, varscan2
- SYNGR4 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs781154537, COSV61225240; called by muse, mutect2, varscan2
- TACR3 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV59200087, COSV59201891; called by muse, mutect2, varscan2
- TCL1A | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68085324; called by muse, mutect2, varscan2
- TESPA1 | c.1108C>A p.Q370K (on ENST00000316577 / NM_001098815.3; = p.Q232K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV57258243; called by muse, mutect2, varscan2
- TEX15 | c.5024G>A p.W1675* (on ENST00000256246; = p.W2058* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as rs1238235577, COSV56344711; called by muse, mutect2
- THAP1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54272916; called by muse, mutect2
- TLR10 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as rs759518971, COSV100458041; called by muse, mutect2, varscan2
- TLR10 | c.1536G>T p.Q512H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100458045; called by muse, mutect2, varscan2
- TLR4 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV62922868; called by muse, mutect2, varscan2
- TLR8 | c.155G>A p.R52H (on ENST00000218032 / NM_138636.5; = p.R70H on NM_016610.4) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs781778459, COSV54317292; called by muse, mutect2, varscan2
- TLR9 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs201740851, COSV59726150; called by muse, mutect2, varscan2
- TMEM135 | c.1342A>T p.T448S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV59698562; called by muse, mutect2, varscan2
- TMEM52B | c.122A>G p.H41R (on ENST00000381923 / NM_001079815.1; = p.H21R on NM_153022.4) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.996); catalogued as COSV53727893; called by muse, mutect2, varscan2
- TNFRSF8 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs1423182224, COSV55795697; called by muse, mutect2, varscan2
- TNNT1 | c.419C>G p.A140G | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV52571387; called by muse, mutect2, varscan2
- TNPO3 | c.1563A>T p.K521N | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV55279997; called by muse, mutect2, varscan2
- TNR | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54879109; called by muse, mutect2, varscan2
- TPSD1 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV52974938; called by muse, mutect2, varscan2
- TRIM9 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs148009813; called by mutect2, varscan2
- TRPV5 | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV54684587; called by muse, mutect2, varscan2
- TSBP1 | c.1283C>G p.A428G (on ENST00000617061; = p.A433G on NM_006781.5) | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66658284; called by muse, mutect2, varscan2
- TTLL9 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.956); catalogued as COSV60591020; called by muse, mutect2, varscan2
- TTN | c.85789A>G p.K28597E (on ENST00000591111; = p.K21173E on NM_003319.4) | Missense Mutation (SNP) | VAF 17/171 reads (10%) | PolyPhen probably damaging (0.994); catalogued as COSV59982721; called by muse, mutect2, varscan2
- TYR | c.859T>G p.S287A | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54473196; called by muse, mutect2
- UBAC2 | c.706G>T p.G236* (on ENST00000403766 / NM_001144072.2; = p.G201* on NM_177967.4) | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV63117630; called by muse, mutect2, varscan2
- UGT1A7 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60835974; called by muse, mutect2, varscan2
- UNC13C | c.6321C>A p.S2107R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV99522593; called by muse, mutect2, varscan2
- UNC5A | c.378C>A p.C126* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | catalogued as COSV56166930; called by muse, mutect2, varscan2
- UNC79 | c.3353T>A p.I1118K (on ENST00000393151 / NM_001346218.2; = p.I941K on NM_020818.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56382114; called by muse, mutect2
- USH2A | c.10166C>A p.T3389N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV56353448; called by muse, mutect2, varscan2
- USP28 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50158458, COSV99136624; called by muse, mutect2, varscan2
- VCAN | c.2960T>C p.V987A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV54102507; called by muse, mutect2, varscan2
- VEGFC | c.522G>T p.M174I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1476932446, COSV54596242; called by muse, mutect2, varscan2
- VNN1 | c.1364C>A p.S455* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63389657; called by muse, mutect2, varscan2
- VSTM2A | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV68289615; called by muse, mutect2, varscan2
- VWA8 | c.4964G>T p.R1655L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64995236, COSV64999830; called by muse, mutect2, varscan2
- WNK3 | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV63613040; called by muse, mutect2, varscan2
- XIRP2 | c.1573C>A p.H525N (on ENST00000628543; = p.H700N on NM_152381.6) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV54692799; called by muse, mutect2, varscan2
- YIPF5 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV50823023; called by muse, mutect2, varscan2
- YTHDF1 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV64832765; called by muse, mutect2, varscan2
- ZBTB2 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV57312215; called by muse, mutect2, varscan2
- ZBTB20 | c.1651A>T p.T551S (on ENST00000474710 / NM_001164342.2; = p.T478S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV61847287; called by muse, mutect2
- ZBTB20 | c.315C>G p.D105E (on ENST00000474710 / NM_001164342.2; = p.D32E on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61847295; called by muse, mutect2, varscan2
- ZFP64 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs760658852, COSV53797979; called by muse, mutect2, varscan2
- ZFYVE9 | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758342320, COSV55092548; called by muse, mutect2, varscan2
- ZIM2 | c.1283T>G p.L428R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV55630216; called by mutect2, varscan2
- ZMAT4 | c.610A>T p.S204C | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV52695198; called by muse, mutect2, varscan2
- ZNF17 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV56921137; called by muse, mutect2, varscan2
- ZNF208 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68103471; called by muse, mutect2, varscan2
- ZNF334 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV61618375; called by muse, mutect2, varscan2
- ZNF385D | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV55751209; called by muse, mutect2
- ZNF536 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100834781, COSV62822031; called by muse, mutect2, varscan2
- ZNF543 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV58627086; called by muse, mutect2, varscan2
- ZNF571 | c.1598A>C p.K533T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV60732841; called by muse, mutect2
- ZNF677 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV61719935; called by muse, varscan2
- ZNF682 | c.719G>T p.W240L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as COSV62066620; called by muse, mutect2, varscan2
- ZNF831 | c.4796G>C p.G1599A | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV64039035; called by muse, mutect2, varscan2
- ZYG11B | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53751751; called by muse, mutect2, varscan2
- ATP1A2 | c.239del p.P80Hfs*90 | Frame Shift Del (DEL) | VAF 20/170 reads (12%) | called by mutect2, varscan2
- DAZAP1 | c.902del p.P301Qfs*34 | Frame Shift Del (DEL) | VAF 25/161 reads (16%) | called by mutect2, pindel, varscan2
- FAM83D | c.977dup p.N328Qfs*9 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.2836del p.A947Qfs*130 | Frame Shift Del (DEL) | VAF 16/157 reads (10%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- MRC1 | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MUC5B | c.9999G>T p.W3333C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); called by mutect2, varscan2
- NBPF1 | c.214A>T p.R72W | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NHSL2 | c.128dup p.N43Kfs*5 (on ENST00000510661; = p.N409Kfs*5 on NM_001013627.2) | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | called by mutect2, pindel, varscan2
- OR2T4 | c.238del p.L80* | Frame Shift Del (DEL) | VAF 58/308 reads (19%) | called by mutect2, varscan2
- POLE | c.893del p.Y298Sfs*2 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- RPL10A | c.475dup p.M159Nfs*20 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.2039A>G p.Q680R | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.155); called by mutect2, varscan2
- TMEM255A | c.688dup p.I230Nfs*18 | Frame Shift Ins (INS) | VAF 34/92 reads (37%) | called by mutect2, varscan2
- TMEM255A | c.687delinsTA p.I230Nfs*18 | Frame Shift Ins (INS) | VAF 39/128 reads (30%) | called by mutect2*, pindel, varscan2*
- TNFRSF19 | c.1145dup p.V383Gfs*78 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- TRPM6 | c.2744C>T p.T915I | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.219); called by muse, mutect2
- ZNF423 | c.2025del p.C675* (on ENST00000563137 / NM_001379286.1; = p.C667* on NM_015069.4) | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, varscan2
- ADGRA2 | c.1545C>T p.I515= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs746210393, COSV100177513, COSV59442490; called by muse, mutect2, varscan2
- AKT3 | c.573A>T p.A191= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV55613104; called by muse, mutect2, varscan2
- ANK2 | c.375A>T p.A125= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52155058; called by muse, mutect2, varscan2
- APLF | c.693A>G p.Q231= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV58143933; called by muse, mutect2, varscan2
- ARFGEF3 | c.2904A>G p.L968= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs779378146, COSV52454783; called by muse, mutect2, varscan2
- ARHGAP18 | c.1827C>T p.L609= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs757563152, COSV63764081; called by muse, mutect2, varscan2
- ARMC9 | c.900C>T p.A300= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100590026; called by muse, mutect2, varscan2
- BPIFB2 | c.1269C>A p.A423= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV50063865; called by muse, mutect2
- CA10 | c.48C>A p.I16= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV53344651; called by muse, mutect2, varscan2
- CATSPERE | c.1089C>T p.S363= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1215967539, COSV63677209; called by muse, mutect2, varscan2
- CD1C | c.741G>C p.L247= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV63806146; called by muse, mutect2, varscan2
- CDH10 | c.1827C>T p.L609= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs373578156; called by mutect2, varscan2
- CFAP61 | c.1728G>A p.K576= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV55625042; called by muse, mutect2, varscan2
- COCH | c.1062C>T p.A354= (on ENST00000216361 / NM_001347720.1; = p.A289= on NM_004086.3) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53550316; called by muse, mutect2, varscan2
- CROCC | c.1638G>A p.Q546= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV65011359; called by muse, mutect2, varscan2
- CSMD3 | c.10488C>A p.A3496= (on ENST00000297405 / NM_001363185.1; = p.A3327= on NM_052900.3) | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV52148291; called by muse, mutect2, varscan2
- CYP3A5 | c.21G>A p.L7= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV56119348; called by muse, mutect2, varscan2
- DCT | c.504G>C p.G168= | Silent (SNP) | VAF 31/229 reads (14%) | catalogued as COSV65468455; called by muse, mutect2, varscan2
- DDX31 | c.1377G>T p.A459= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV60135142; called by muse, mutect2, varscan2
- DENND2A | c.141G>A p.K47= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV52049847; called by muse, mutect2
- DOCK3 | c.4830T>A p.P1610= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV56514003; called by muse, mutect2, varscan2
- EPB41 | c.2334C>T p.D778= (on ENST00000343067 / NM_001166005.2; = p.D569= on NM_203342.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV58042535; called by muse, mutect2
- EPHB1 | c.2595G>T p.R865= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs369946044, COSV67657861; called by mutect2, varscan2
- EXO1 | c.1488A>T p.A496= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV62217130; called by muse, mutect2, varscan2
- EXOC3L2 | c.1767G>A p.E589= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1249733126, COSV52972660; called by muse, mutect2, varscan2
- FAM120B | c.402C>T p.P134= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV53002875; called by muse, mutect2, varscan2
- FCMR | c.177T>A p.G59= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as rs779507191, COSV65567545; called by muse, mutect2, varscan2
- FCRL1 | c.795C>G p.S265= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV63824632; called by muse, mutect2, varscan2
- FRMPD4 | c.51G>C p.T17= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV66213341, COSV66213803; called by muse, mutect2, varscan2
- GLYATL1 | c.798G>C p.V266= (on ENST00000317391 / NM_001354699.1; = p.V297= on NM_080661.4) | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV55608292; called by muse, mutect2
- HBD | c.231T>C p.A77= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV53082306; called by muse, mutect2, varscan2
- HEPHL1 | c.63G>A p.L21= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV59890975; called by muse, mutect2, varscan2
- IGLON5 | c.192C>A p.A64= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54535370; called by mutect2, varscan2
- IL23R | c.855G>A p.E285= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs911019244; called by muse, mutect2
- KCNK17 | c.684G>T p.V228= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV64685132; called by muse, mutect2, varscan2
- KRT74 | c.411C>A p.R137= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV59770953; called by muse, mutect2, varscan2
- LAD1 | c.618G>T p.V206= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as COSV66212328; called by muse, mutect2, varscan2
- LILRB3 | c.639C>G p.P213= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as COSV54433377; called by muse, mutect2, varscan2
- MALT1 | c.2223A>T p.A741= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV61934578; called by muse, mutect2
- MAST2 | c.4005C>A p.R1335= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV63617498; called by muse, mutect2, varscan2
- MED13 | c.4278A>C p.L1426= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV67262909; called by muse, mutect2, varscan2
- MMP2 | c.963G>A p.E321= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs371712644; called by mutect2, varscan2
- NBEA | c.7021A>C p.R2341= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV59774106; called by muse, mutect2, varscan2
- NCOA5 | c.474A>T p.P158= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV51643682; called by muse, mutect2, varscan2
- NLRP8 | c.2890C>T p.L964= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs535321291, COSV52585718; called by muse, mutect2, varscan2
- OBSL1 | c.3147T>A p.P1049= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV54705055; called by muse, mutect2, varscan2
- OLIG2 | c.24G>T p.V8= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV60972405; called by muse, mutect2, varscan2
- OR2M4 | c.69C>A p.T23= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs1229602747, COSV60707792; called by muse, mutect2, varscan2
- OR51G1 | c.627G>T p.V209= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV58968908, COSV58968962; called by muse, mutect2, varscan2
- OR52E2 | c.969G>T p.T323= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV58611715, COSV58612319; called by muse, mutect2, varscan2
- OR8B8 | c.108G>A p.V36= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1030047584, COSV60144242, COSV60144850; called by muse, mutect2, varscan2
- PDZRN3 | c.1977C>A p.A659= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV55195932; called by muse, mutect2, varscan2
- PGS1 | c.1002G>A p.Q334= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV53144485; called by muse, mutect2, varscan2
- PIP4P2 | c.696C>T p.L232= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV53438189, COSV99575666; called by muse, mutect2, varscan2
- PLA2G4C | c.1146C>T p.H382= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV62784935; called by muse, mutect2, varscan2
- PTPRB | c.381C>A p.L127= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV51729030, COSV99316762; called by muse, mutect2, varscan2
- PTPRC | c.1656T>C p.F552= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV61409322; called by muse, mutect2
- PTPRF | c.1734C>T p.Y578= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV63444167; called by muse, mutect2, varscan2
- RNF213 | c.6750C>T p.F2250= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as rs1456138338, COSV60394625, COSV60403312; called by muse, mutect2
- SAMD9L | c.1881G>T p.V627= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as COSV59080741; called by muse, mutect2, varscan2
- SCAP | c.459G>C p.L153= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV55560463; called by muse, varscan2
- SEMA6A | c.840C>A p.R280= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV57309584; called by muse, mutect2, varscan2
- SEPTIN7 | c.918T>C p.Y306= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs767984090, COSV63254537; called by mutect2, varscan2
- SERPINA11 | c.105C>A p.P35= | Silent (SNP) | VAF 24/175 reads (14%) | catalogued as rs1174562949, COSV58241546; called by muse, mutect2, varscan2
- SH3PXD2A | c.1380G>A p.Q460= (on ENST00000369774 / NM_001365079.1; = p.Q432= on NM_014631.2) | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV60116695, COSV60118372; called by muse, mutect2, varscan2
- SIGLEC8 | c.351G>A p.R117= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV58473124; called by muse, mutect2
- SNRPF | c.163T>C p.L55= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV57136411; called by muse, mutect2
- SNX10 | c.390T>A p.I130= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100640137; called by muse, mutect2, varscan2
- SPAST | c.129G>A p.E43= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV59513636; called by muse, mutect2, varscan2
- SPATA16 | c.1356C>A p.S452= | Silent (SNP) | VAF 42/199 reads (21%) | catalogued as COSV63528313; called by muse, mutect2, varscan2
- STK16 | c.531G>T p.V177= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV99850857; called by muse, mutect2
- STK31 | c.1182A>T p.I394= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs766743451, COSV63455295; called by muse, mutect2, varscan2
- TAL1 | c.595C>A p.R199= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53745655, COSV53746030; called by muse, mutect2, varscan2
- TBC1D21 | c.816G>T p.V272= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV55994972; called by muse, mutect2, varscan2
- TENM1 | c.3231T>A p.L1077= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV64429369; called by muse, mutect2, varscan2
- TEPP | c.225C>A p.S75= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV52042938; called by mutect2, varscan2
- TNFRSF17 | c.444T>A p.A148= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV50000413; called by mutect2, varscan2
- TRPM4 | c.585G>T p.R195= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV53261709; called by mutect2, varscan2
- TSKS | c.33G>A p.Q11= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV55874260; called by muse, mutect2, varscan2
- UBA7 | c.1368G>T p.L456= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as COSV61091958; called by muse, mutect2, varscan2
- UNC119B | c.459A>T p.T153= | Silent (SNP) | VAF 19/185 reads (10%) | catalogued as COSV60866064; called by muse, mutect2, varscan2
- USH2A | c.14916C>A p.R4972= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV56353429; called by muse, mutect2, varscan2
- VPS13D | c.2871G>C p.A957= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV50631308, COSV50656387; called by muse, mutect2, varscan2
- VPS35L | c.1398A>G p.R466= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs1362671828, COSV51980730, COSV51992715; called by muse, mutect2, varscan2
- VPS54 | c.2097A>T p.A699= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV55439455; called by muse, mutect2, varscan2
- YTHDC2 | c.153C>T p.I51= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs150619659; called by muse, mutect2, varscan2
- ZC3H12B | c.2421C>A p.I807= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV59047278; called by muse, mutect2, varscan2
- ZNF202 | c.351A>T p.A117= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV60246850; called by muse, mutect2, varscan2
- AC073310.1 | n.428C>A | RNA (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- AC244258.1 | n.354A>T | RNA (SNP) | VAF 35/161 reads (22%) | called by muse, mutect2, varscan2
- C11orf68 | c.*2G>C | 3'UTR (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100437014, COSV100437168; called by muse, mutect2, varscan2
- C20orf197 | n.549A>T | RNA (SNP) | VAF 12/50 reads (24%) | called by muse, varscan2
- CDRT15P3 | n.525G>T | RNA (SNP) | VAF 15/120 reads (13%) | catalogued as rs746232854; called by muse, mutect2, varscan2
- DCHS2 | n.7652G>A | RNA (SNP) | VAF 10/33 reads (30%) | catalogued as COSV61770093; called by muse, mutect2, varscan2
- LLCFC1 | c.158-67C>A | Intron (SNP) | VAF 19/58 reads (33%) | catalogued as rs1235018966, COSV62334272; called by muse, mutect2, varscan2
- MIR410 | n.6C>T | RNA (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- MIR520A | n.55A>C | RNA (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- MIR892A | n.24C>G | RNA (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- NFASC | c.2471-1334G>A | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100362844; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1185A>G | RNA (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- SEC14L1 | c.-240+135G>T | Intron (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100811362; called by muse, mutect2
